Somatic mutation profile of tumor specimen TCGA-2Y-A9GS-01A (aliquot TCGA-2Y-A9GS-01A-12D-A382-10) from TCGA case TCGA-2Y-A9GS, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G2; Age at diagnosis: 58.4 years (21,318 days).
Specimen TCGA-2Y-A9GS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 174efc9d-778a-4117-b05f-c0f7b07466ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Y-A9GS-10A (Blood Derived Normal), aliquot TCGA-2Y-A9GS-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db66eeb5-4e3e-4d10-8dbe-a6c0bf9f1c1d

The open-access MAF lists 73 somatic variants for this specimen: 60 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 12, Nonsense Mutation 2, Frame Shift Ins 2, Frame Shift Del 2, Splice Site 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 35/76 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- AATK | c.3967G>A p.A1323T (on ENST00000326724 / NM_001080395.3; = p.A1220T on NM_004920.2) | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs762246513, COSV100352906; called by muse, mutect2, varscan2
- ABRA | c.901C>A p.R301S | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs182944429, COSV100357605, COSV100357711; called by muse, mutect2, varscan2
- ADGRL2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99589717; called by muse, mutect2, varscan2
- ANKRD44 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as rs750473345, COSV99985292; called by muse, mutect2, varscan2
- ARFGEF3 | c.3190dup p.E1064Gfs*63 | Frame Shift Ins (INS) | VAF 54/181 reads (30%) | catalogued as COSV52451478; called by mutect2, pindel, varscan2
- ASTN1 | c.2003T>G p.M668R | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV99922173; called by muse, mutect2
- BASP1 | c.395G>A p.S132N | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as rs766369296, COSV100493768; called by muse, mutect2, varscan2
- BAZ2A | c.3836A>G p.H1279R | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.543); catalogued as rs367656362; called by muse, mutect2, varscan2
- CAVIN1 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs144331065; called by muse, mutect2, varscan2
- CEP68 | c.2153A>C p.E718A | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV99561021; called by muse, mutect2, varscan2
- CLASP2 | c.579G>C p.E193D | Missense Mutation (SNP) | VAF 127/312 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.107); catalogued as COSV100223673; called by muse, mutect2, varscan2
- CTDSP1 | c.531T>G p.F177L | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99812003; called by muse, mutect2, varscan2
- CWF19L1 | c.137G>C p.G46A | Missense Mutation (SNP) | VAF 217/372 reads (58%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.541); catalogued as COSV100821549; called by muse, mutect2, varscan2
- CYC1 | c.163C>G p.R55G | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.254); catalogued as COSV100010466; called by muse, mutect2, varscan2
- DIDO1 | c.6443A>G p.D2148G | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs762714731, COSV99826220; called by muse, mutect2, varscan2
- DNAJB1 | c.675C>A p.D225E | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as rs775147909, COSV54317465, COSV54318351, COSV99584162; called by muse, mutect2, varscan2
- EYA1 | c.1556T>A p.I519N | Missense Mutation (SNP) | VAF 104/333 reads (31%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.715); catalogued as COSV100379654; called by muse, mutect2, varscan2
- FCRL4 | c.188G>T p.W63L | Missense Mutation (SNP) | VAF 80/238 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV54859462; called by muse, mutect2, varscan2
- FRMD4B | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as rs527581690, COSV101273510; called by muse, mutect2
- GALNT7 | c.595T>C p.Y199H | Missense Mutation (SNP) | VAF 71/129 reads (55%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV99397549; called by muse, mutect2, varscan2
- GEM | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771063860, COSV52599511; called by muse, mutect2, varscan2
- GFRAL | c.626C>G p.T209R | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100474756, COSV100475369; called by muse, mutect2, varscan2
- HEATR3 | c.409G>T p.G137* | Nonsense Mutation (SNP) | VAF 48/157 reads (31%) | catalogued as COSV53530393, COSV99589985; called by muse, varscan2
- HEATR3 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV99589988; called by muse, varscan2
- HIPK4 | c.1778C>A p.P593H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.552); catalogued as COSV99396781; called by muse, mutect2, varscan2
- HSP90B1 | c.1931C>A p.P644Q | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100236596; called by muse, mutect2, varscan2
- KRT81 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs760672911, COSV100576988; called by muse, mutect2, varscan2
- KRTAP13-3 | c.122G>T p.C41F | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.355); catalogued as COSV100481759; called by muse, mutect2, varscan2
- L3MBTL4 | c.1165C>T p.H389Y | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99529561; called by muse, mutect2
- LILRA4 | c.525G>T p.K175N | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.447); catalogued as COSV99393210; called by muse, mutect2, varscan2
- LY75 | c.2773A>T p.K925* | Nonsense Mutation (SNP) | VAF 49/149 reads (33%) | catalogued as COSV99716613; called by muse, mutect2, varscan2
- MAP4K2 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as rs764475692, COSV53644758; called by muse, mutect2, varscan2
- MED12L | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs376895313, COSV56371084; called by muse, mutect2
- MEGF10 | c.744C>A p.H248Q | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.914); catalogued as COSV99175049; called by muse, mutect2, varscan2
- MGAT5 | c.458A>G p.Y153C | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV99924656; called by muse, mutect2, varscan2
- MRPL19 | c.554A>G p.D185G | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV100718843; called by muse, mutect2, varscan2
- NES | c.3617G>T p.G1206V | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs754373045, COSV100957899; called by muse, mutect2, varscan2
- NLRP14 | c.3035G>A p.C1012Y | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as COSV100205128; called by muse, mutect2
- OR52R1 | c.913A>G p.R305G | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV100617746; called by muse, mutect2, varscan2
- PCDHGA6 | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.009); catalogued as rs748938190, COSV99531635; called by muse, mutect2, varscan2
- PDE8A | c.836G>T p.C279F | Missense Mutation (SNP) | VAF 73/256 reads (29%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.468); catalogued as COSV100052015; called by muse, mutect2, varscan2
- PGM3 | c.1288T>A p.L430M | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99382236; called by muse, mutect2, varscan2
- PTPRN | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99834072; called by muse, mutect2, varscan2
- RXRG | c.458T>C p.V153A | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100717636; called by muse, mutect2, varscan2
- SFMBT2 | c.2485G>A p.V829M | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62808673; called by muse, mutect2, varscan2
- SMTN | c.2294A>G p.K765R | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100294577; called by muse, mutect2, varscan2
- SNCAIP | c.634C>A p.P212T | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99749297; called by muse, mutect2, varscan2
- TECPR1 | c.1193T>G p.F398C | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs375012059; called by muse, mutect2, varscan2
- TKFC | c.1687G>T p.A563S | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV99582505; called by muse, mutect2, varscan2
- TTN | c.46512G>T p.K15504N (on ENST00000591111; = p.K8080N on NM_003319.4) | Missense Mutation (SNP) | VAF 36/92 reads (39%) | PolyPhen probably damaging (0.997); catalogued as COSV100618277; called by muse, mutect2, varscan2
- WNT8A | c.119C>T p.T40M | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.959); catalogued as rs528082347, COSV64231019; called by muse, mutect2, varscan2
- ZBTB7C | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs775360190, COSV59689460; called by muse, mutect2
- ZNF326 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100438158; called by muse, mutect2, varscan2
- ALB | c.1395_1402del p.E466Kfs*21 | Frame Shift Del (DEL) | VAF 82/161 reads (51%) | called by mutect2, pindel, varscan2
- ARHGAP45 | c.422-1G>C p.X141_splice | Splice Site (SNP) | VAF 2/8 reads (25%) | called by muse, mutect2
- IGKV3-20 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 91/281 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- IL1RAP | c.1061dup p.R355Kfs*43 | Frame Shift Ins (INS) | VAF 31/112 reads (28%) | called by mutect2, pindel, varscan2
- KEAP1 | c.1064_1088del p.L355Sfs*37 | Frame Shift Del (DEL) | VAF 36/76 reads (47%) | called by mutect2, pindel, varscan2
- STUB1 | c.595_612+14del p.X199_splice | Splice Site (DEL) | VAF 54/189 reads (29%) | called by mutect2, pindel
- DRD1 | c.132C>G p.V44= | Silent (SNP) | VAF 53/133 reads (40%) | catalogued as COSV101192482, COSV67104185, COSV67104552; called by muse, mutect2, varscan2
- EDIL3 | c.375T>G p.V125= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV99677315; called by muse, mutect2, varscan2
- EXD1 | c.1080T>C p.F360= | Silent (SNP) | VAF 21/152 reads (14%) | catalogued as COSV100153697; called by muse, mutect2, varscan2
- GABRG1 | c.1191G>A p.P397= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as rs765340305, COSV54953645; called by muse, mutect2, varscan2
- KRT1 | c.612G>A p.Q204= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV99358841; called by muse, mutect2, varscan2
- LAMB4 | c.3628C>T p.L1210= | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as COSV99224493; called by muse, mutect2, varscan2
- OBSCN | c.14184C>A p.P4728= | Silent (SNP) | VAF 41/134 reads (31%) | catalogued as rs756685253, COSV99480407; called by muse, mutect2, varscan2
- SLC25A48 | c.276C>T p.C92= | Silent (SNP) | VAF 42/117 reads (36%) | catalogued as rs368023667, COSV99192019; called by muse, mutect2, varscan2
- SLC5A3 | c.132C>T p.R44= | Silent (SNP) | VAF 37/105 reads (35%) | catalogued as rs1350675116, COSV100757962; called by muse, mutect2, varscan2
- ST8SIA6 | c.858G>C p.T286= | Silent (SNP) | VAF 91/235 reads (39%) | catalogued as COSV101112158, COSV66471233; called by muse, mutect2, varscan2
- TKTL1 | c.1614G>A p.P538= | Silent (SNP) | VAF 103/147 reads (70%) | catalogued as rs1194094334, COSV54215183; called by muse, mutect2, varscan2
- TNFRSF25 | c.345T>C p.C115= | Silent (SNP) | VAF 14/133 reads (11%) | catalogued as COSV100556908; called by muse, mutect2, varscan2
- CWC27 | c.-1G>C | 5'UTR (SNP) | VAF 35/129 reads (27%) | catalogued as COSV101126523; called by muse, mutect2, varscan2
